Somatic mutation profile of tumor specimen MBCProject_0852_T1_WES (aliquot MBCProject_0852_T1_WES_1) from CMI case MBCProject_0852, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.8 years (18,184 days).
Specimen MBCProject_0852_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c90aeb4-b76d-423f-bba1-338b2a837e9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0852_SALIVA (Saliva), aliquot MBCProject_0852_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1de76ec9-9729-4cd2-92c2-e40b48db6024

The open-access MAF lists 131 somatic variants for this specimen: 93 protein-altering or splice-affecting, 23 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 23, Intron 6, Splice Site 4, Nonsense Mutation 4, RNA 3, Frame Shift Del 2, 5'UTR 2, Splice Region 2, 5'Flank 2, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762137050, COSV51621604; called by muse, varscan2
- ACVR2B | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs776754289, COSV61701092; called by muse, mutect2, varscan2
- ATP1A2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs181618883, COSV63404142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC186 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV65161760; called by muse, mutect2, varscan2
- CFHR5 | c.1236A>T p.K412N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56820377; called by muse, mutect2, varscan2
- CMTM7 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58550058; called by muse, mutect2, varscan2
- COL12A1 | c.997G>T p.V333F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.463); catalogued as COSV59401108; called by muse, mutect2
- CSMD3 | c.3772C>A p.P1258T (on ENST00000297405 / NM_001363185.1; = p.P1154T on NM_052900.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52324820; called by muse, mutect2, varscan2
- CYP2D7 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV63852216; called by muse, varscan2
- CYP4F12 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200041881, COSV61173156; called by muse, mutect2, varscan2
- DDX3X | c.278G>A p.G93E (on ENST00000399959; = p.G94E on NM_001356.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1374495935, COSV67864041; called by muse, mutect2, varscan2
- DNAH8 | c.5119G>A p.D1707N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs267601015, COSV100543697, COSV59422745; called by muse, mutect2
- GPR18 | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs775292571; called by muse, mutect2, varscan2
- GYPA | c.137-7T>C | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as rs1270978859; called by muse, mutect2, varscan2
- HRNR | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.146); catalogued as COSV64254203; called by muse, mutect2, varscan2
- MBNL3 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs773619074; called by muse, varscan2
- OBSCN | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.981); catalogued as rs1327795074; called by muse, mutect2, varscan2
- OR2T33 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100531971, COSV58815594, COSV58817591; called by muse, mutect2
- OS9 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776352883; called by muse, varscan2
- PCDHGB2 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs779307225; called by muse, mutect2, varscan2
- PHF8 | c.2923G>C p.E975Q (on ENST00000357988 / NM_001184896.1; = p.E939Q on NM_015107.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1414664364; ClinVar: uncertain significance; called by muse, mutect2
- PTP4A3 | c.77C>G p.T26S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs888702341; called by muse, mutect2, varscan2
- RBMXL3 | c.2688T>G p.S896R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.766); catalogued as COSV104395695; called by muse, mutect2, varscan2
- SCN4A | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as rs1429665339; called by muse, mutect2, varscan2
- SCUBE1 | c.1601G>T p.R534M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV62614042; called by muse, mutect2, varscan2
- SETD5 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs567415895; called by muse, mutect2, varscan2
- SSTR2 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs139033946; called by muse, mutect2, varscan2
- STARD8 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs201149959; called by muse, mutect2, varscan2
- TMC7 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100432681; called by mutect2, varscan2
- TSPAN31 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs763198055, COSV57276750, COSV99226038; called by muse, mutect2, varscan2
- ZBTB33 | c.1283C>A p.S428* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV58534689; called by muse, mutect2, varscan2
- ADCY2 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ADCY9 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMC4 | c.1429A>G p.R477G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ATP8B4 | c.2471A>C p.K824T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRCA1 | c.3254G>T p.R1085I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by mutect2, varscan2
- C11orf45 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CCDC7 | c.488G>T p.W163L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.038); called by muse, mutect2
- CCDC88A | c.2059T>G p.F687V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH6 | c.1115T>A p.I372N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CECR2 | c.3173G>T p.G1058V (on ENST00000342247 / NM_001290047.2; = p.G874V on NM_001290046.1) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CFAP45 | c.1531C>G p.R511G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CNTN1 | c.2980_2980+12del p.X994_splice | Splice Site (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- COL1A1 | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYFIP2 | c.3190G>T p.G1064W (on ENST00000616178 / NM_001291722.2; = p.G1039W on NM_014376.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP11B2 | c.1505T>C p.I502T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2
- CYP4F3 | c.968A>C p.D323A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DLG1 | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DUOX2 | c.2171A>G p.E724G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPPK1 | c.2177C>A p.T726K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EVA1B | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by mutect2, varscan2
- FER1L6 | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- FREM3 | c.4225A>C p.T1409P | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- GC | c.1165-1G>C p.X389_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- GTF3C4 | c.503G>C p.S168T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IFT122 | c.1772A>G p.Q591R (on ENST00000348417 / NM_052989.3; = p.Q532R on NM_018262.4) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IKBKE | c.1556G>C p.S519T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ING3 | c.267+4A>T | Splice Region (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- KSR1 | c.670G>T p.G224C (on ENST00000644974 / NM_001367810.1; = p.G87C on NM_014238.2) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- LARGE1 | c.1797_1810del p.L600Vfs*48 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- LIX1L | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2
- MROH2B | c.3248A>G p.D1083G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MUC12 | c.13222G>T p.A4408S (on ENST00000379442; = p.A4265S on NM_001164462.1) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.15); called by muse, varscan2
- MYT1L | c.2009C>A p.P670H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NAP1L1 | c.538T>A p.L180M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NEURL4 | c.4042G>T p.E1348* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- NPC1L1 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- NRIP1 | c.523T>A p.L175I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- OAS1 | c.710_754del p.V237_T251del | In Frame Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- OR10Z1 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OTUD6A | c.453C>A p.H151Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDCD1 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2
- PENK | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, varscan2
- PGRMC1 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RBM47 | c.1180A>G p.R394G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGPD3 | c.1730T>A p.V577E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.18); called by mutect2, varscan2
- RRM2 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RTL9 | c.695T>A p.L232* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- SLC24A4 | c.1741T>A p.W581R | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLCO4A1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- STAMBP | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAF7L | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TG | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TGFBR3 | c.538_568+6del p.X180_splice | Splice Site (DEL) | VAF 27/147 reads (18%) | called by mutect2, pindel
- THSD4 | c.443T>G p.L148R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM214 | c.1011-2A>C p.X337_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- TNRC6A | c.4163G>T p.G1388V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TRIM2 | c.1781A>G p.N594S (on ENST00000437508; = p.N621S on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- UGT2A2 | c.272A>C p.N91T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UROD | c.219_253del p.R75Hfs*44 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel
- WFS1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- ATP8B1 | c.1350T>C p.Y450= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- COMMD5 | c.624A>C p.L208= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- DCDC1 | c.4554C>T p.S1518= (on ENST00000597505 / NM_001367979.1; = p.S625= on NM_020869.3) | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as rs1237416222, COSV58002645; called by muse, mutect2
- DNAH2 | c.222A>G p.A74= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- EPB41L3 | c.3135A>C p.A1045= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- FSTL1 | c.444C>A p.I148= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1308C>T p.N436= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- MAST1 | c.258A>G p.G86= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- MCF2 | c.2413A>C p.R805= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- PATZ1 | c.96G>A p.Q32= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1426174769; called by muse, varscan2
- PLEC | c.7770T>G p.A2590= (on ENST00000322810 / NM_201380.4; = p.A2480= on NM_000445.5) | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- PPP2R3B | c.654C>T p.V218= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- RETREG1 | c.600C>G p.V200= (on ENST00000306320 / NM_001034850.2; = p.V59= on NM_019000.4) | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- RNF138 | c.648A>G p.Q216= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs773379320; called by muse, mutect2, varscan2
- SETX | c.4143A>C p.A1381= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1053045962; called by muse, mutect2, varscan2
- SLC4A4 | c.2043C>T p.L681= (on ENST00000264485 / NM_001098484.3; = p.L637= on NM_003759.4) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs754449686; called by muse, mutect2, varscan2
- TIGAR | c.636C>T p.D212= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs775799671; called by muse, mutect2, varscan2
- TMEM87A | c.1359C>T p.L453= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- USP24 | c.1488T>C p.I496= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- VCAM1 | c.1914A>G p.K638= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- VCAN | c.2376T>A p.T792= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV54112172; called by muse, mutect2, varscan2
- VIM | c.702G>A p.L234= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV99812944; called by muse, mutect2, varscan2
- WDR17 | c.1458T>C p.I486= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- AHSA2P | n.4C>G | RNA (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2
- AL353804.4 | chrX:73823440 G>A | 5'Flank (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- C12orf77 | n.416_426del | RNA (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- CUBN | c.7534-41G>A | Intron (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- IGHD1-1 | chr14:105922595 T>G | 5'Flank (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- LAMA1 | c.8095-30C>T | Intron (SNP) | VAF 16/83 reads (19%) | catalogued as rs567274914, COSV101057341; called by muse, mutect2, varscan2
- PLA2R1 | c.-16A>T | 5'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as rs772389901; called by muse, mutect2, varscan2
- PSMD1 | c.-64G>C | 5'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- RAD51D | c.*677G>C | 3'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, varscan2
- RPL10 | c.*133C>T | 3'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as rs782160948; called by muse, varscan2
- RPS21 | c.186+25_186+43del | Intron (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- SHB | c.838+545T>G | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- TLX1NB | n.1593C>A | RNA (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- TTLL1 | c.114-337G>C | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, varscan2
- WNK1 | c.2140-2517T>A | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
